Somatic mutation profile of tumor specimen TCGA-W3-AA1Q-06A (aliquot TCGA-W3-AA1Q-06A-11D-A38G-08) from TCGA case TCGA-W3-AA1Q, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 60.0 years (21,915 days).
Specimen TCGA-W3-AA1Q-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2db011b8-dcdd-4992-a7ae-206fb9ab9380.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W3-AA1Q-10A (Blood Derived Normal), aliquot TCGA-W3-AA1Q-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55f16ae2-891d-46e9-bf00-9f296656aa25

The open-access MAF lists 1,097 somatic variants for this specimen: 732 protein-altering or splice-affecting, 338 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 661, Silent 338, Nonsense Mutation 41, Splice Region 14, Intron 14, Splice Site 8, RNA 8, Frame Shift Del 4, Translation Start Site 3, 5'Flank 3, 5'UTR 2, Frame Shift Ins 1.

Variants (750 of 1,097; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DSG2 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs121913012, CM060963, COSV55201967; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- EBF2 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 24/92 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV68776268, COSV68778111; called by muse, mutect2, varscan2
- GJA8 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs864309703, CM162287, COSV53791343; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs1057519732, COSV61068297; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RERE | c.248dup p.S84Vfs*4 | Frame Shift Ins (INS) | VAF 67/192 reads (35%) | catalogued as rs1557461427; ClinVar: pathogenic; called by mutect2, varscan2
- A1CF | c.468G>A p.M156I | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV50958517; called by muse, mutect2, varscan2
- ABCA12 | c.5123G>A p.R1708K (on ENST00000272895 / NM_173076.3; = p.R1390K on NM_015657.3) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99792044; called by muse, mutect2, varscan2
- ABCA2 | c.4826C>T p.S1609F (on ENST00000614293; = p.S1579F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as COSV99688444; called by muse, varscan2
- ABCA8 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV99286928; called by muse, mutect2, varscan2
- ABCC8 | c.4426G>A p.E1476K | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100217728; called by muse, mutect2, varscan2
- ABHD16A | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1183486990, COSV101013364; called by muse, mutect2, varscan2
- AC132217.2 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV100324235; called by muse, mutect2, varscan2
- ACKR3 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745666707, COSV56020972; called by muse, mutect2, varscan2
- ACOXL | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV61325203; called by muse, mutect2, varscan2
- ACP3 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as COSV60488646; called by muse, mutect2, varscan2
- ACSL3 | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs776538313, COSV62481117; called by muse, mutect2, varscan2
- ACTN2 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV100857027; called by muse, mutect2, varscan2
- ADAM15 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.61); catalogued as rs751806321, COSV99665348; called by muse, mutect2, varscan2
- ADAM28 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303422157, COSV56099428, COSV56099824; called by muse, mutect2, varscan2
- ADAMTS13 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.122); catalogued as COSV100747217; called by muse, mutect2
- ADGRB3 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs267601100, COSV101001608; called by muse, mutect2, varscan2
- ADGRF5 | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99346436; called by muse, mutect2, varscan2
- ADGRG7 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs909433668, COSV56293550; called by muse, mutect2, varscan2
- ADH1B | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV59294987; called by muse, mutect2, varscan2
- AFDN | c.3883G>A p.A1295T | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.013); catalogued as COSV100653547; called by muse, mutect2, varscan2
- AFF2 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 52/63 reads (83%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs200490489, COSV99663239; called by muse, mutect2, varscan2
- AGMO | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61119370; called by muse, mutect2, varscan2
- AHNAK | c.4682A>G p.K1561R | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99949626; called by muse, mutect2, varscan2
- AHNAK2 | c.13502C>T p.S4501F | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100318963; called by muse, mutect2, varscan2
- AHNAK2 | c.8245C>T p.P2749S | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV100318964; called by muse, mutect2, varscan2
- AHNAK2 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.039); catalogued as COSV100318965, COSV60911105; called by muse, mutect2, varscan2
- AK7 | c.2131C>T p.L711= | Splice Region (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99967543; called by muse, mutect2, varscan2
- ALCAM | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.999); catalogued as COSV100065751; called by muse, mutect2, varscan2
- ALG12 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | PolyPhen probably damaging (1); catalogued as rs748563631, COSV100427217; called by muse, mutect2, varscan2
- ALOX5 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs369176350; called by muse, mutect2, varscan2
- ALPK2 | c.4330G>A p.E1444K | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs370248466, COSV64490192; called by muse, mutect2
- AMBN | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV100534356; called by muse, mutect2
- AMBRA1 | c.2464C>T p.H822Y (on ENST00000458649 / NM_001367468.1; = p.H732Y on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.572); catalogued as COSV100095356; called by muse, mutect2, varscan2
- AMER1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100367055, COSV57658549; called by muse, mutect2, varscan2
- ANK3 | c.2671G>A p.E891K (on ENST00000280772 / NM_001320874.2; = p.E25K on NM_001149.3) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs753404464, COSV55062070, COSV99779502; called by muse, mutect2, varscan2
- ANK3 | c.2125C>T p.R709* | Nonsense Mutation (SNP) | VAF 32/94 reads (34%) | catalogued as COSV55045350; called by muse, mutect2, varscan2
- ANK3 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs4635033, COSV55064748; called by muse, mutect2, varscan2
- ANKRD17 | c.2527C>T p.L843F | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV100429984; called by muse, mutect2, varscan2
- ANKRD30A | c.1747C>T p.P583S (on ENST00000611781; = p.P527S on NM_052997.2) | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.968); catalogued as rs772585483, COSV100654453; called by muse, mutect2, varscan2
- ANKRD30A | c.2461C>T p.P821S (on ENST00000611781; = p.P765S on NM_052997.2) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.901); catalogued as rs1299131572; called by mutect2, varscan2
- ANO2 | c.1654G>A p.V552M (on ENST00000356134 / NM_001278597.3; = p.V556M on NM_001278596.3) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100500052; called by muse, mutect2
- ANO5 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.996); catalogued as COSV100202226; called by muse, mutect2, varscan2
- AOX1 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1414375899, COSV101022237; called by muse, mutect2, varscan2
- AOX1 | c.3206A>T p.N1069I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1309482334, COSV99613793; called by muse, mutect2, varscan2
- AP3D1 | c.3155C>T p.P1052L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as COSV100643054; called by muse, mutect2, varscan2
- APLNR | c.1057G>C p.G353R | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV99951672; called by muse, mutect2, varscan2
- AREG | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV99144397; called by muse, mutect2, varscan2
- ARHGAP24 | c.2105G>A p.R702Q (on ENST00000395184 / NM_001025616.3; = p.R609Q on NM_031305.3) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1195125967, COSV51990793; called by muse, mutect2, varscan2
- ARHGAP31 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV99957112, COSV99957743; called by muse, mutect2, varscan2
- ARHGAP9 | c.2155C>T p.R719W (on ENST00000393797 / NM_001319850.2; = p.R700W on NM_032496.4) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774074348, COSV99954717, COSV99954812; called by muse, mutect2, varscan2
- ARHGEF17 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV99736797; called by muse, mutect2, varscan2
- ARMC4 | c.2143G>A p.G715R | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100537423; called by muse, mutect2, varscan2
- ARMC4 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as rs866557612, COSV100537424; called by muse, mutect2, varscan2
- ARMC4 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53467358; called by muse, mutect2, varscan2
- ARMC4 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.164); catalogued as rs867782052, COSV53463722; called by muse, mutect2, varscan2
- ART1 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs752333152, COSV51704129; called by muse, mutect2, varscan2
- ASAP2 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV55639737; called by muse, mutect2, varscan2
- ASH1L | c.4933C>T p.H1645Y | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.063); catalogued as COSV100853605; called by muse, mutect2, varscan2
- ASTN1 | c.3643C>T p.P1215S | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100707693, COSV62492095; called by muse, mutect2, varscan2
- ASTN1 | c.2379G>A p.G793= | Splice Region (SNP) | VAF 13/76 reads (17%) | catalogued as COSV99923084; called by muse, mutect2, varscan2
- ASTN1 | c.2378G>A p.G793E | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867077481, COSV99921157, COSV99923086; called by muse, mutect2, varscan2
- ATP10B | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs1439840167, COSV58778473; called by muse, mutect2, varscan2
- ATP1A4 | c.1759G>A p.D587N | Missense Mutation (SNP) | VAF 81/149 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV63626132; called by muse, mutect2, varscan2
- ATP2A2 | c.2068C>A p.L690I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV100428899; called by muse, mutect2, varscan2
- ATP6V0D2 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200334003; called by muse, mutect2, varscan2
- ATP9A | c.682C>G p.P228A | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100125633, COSV58764528; called by muse, mutect2, varscan2
- ATR | c.4912C>T p.Q1638* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV100638590; called by muse, mutect2, varscan2
- AUTS2 | c.1741C>T p.H581Y | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.705); catalogued as COSV100719562; called by muse, mutect2, varscan2
- AVPR1B | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868925962, COSV100899448, COSV65637750; called by muse, mutect2, varscan2
- AXL | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99997271; called by muse, mutect2, varscan2
- B3GALT4 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs764769925, COSV101005715; called by muse, mutect2, varscan2
- B3GNT4 | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99928387; called by muse, mutect2, varscan2
- BANK1 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV59845768; called by muse, mutect2, varscan2
- BAP1 | c.1290C>G p.S430R | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.078); catalogued as rs773592865, COSV99964511; called by muse, mutect2, varscan2
- BARX2 | c.563G>A p.W188* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV99859028; called by muse, mutect2, varscan2
- BECN1 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100831164, COSV100831186; called by muse, mutect2, varscan2
- BMP5 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63702572; called by muse, mutect2, varscan2
- BNC2 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 29/99 reads (29%) | catalogued as COSV66153838; called by muse, mutect2, varscan2
- BNIP5 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1387133764, COSV101465189; called by muse, mutect2, varscan2
- BRINP3 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV100819480; called by muse, mutect2, varscan2
- BRWD3 | c.4229C>A p.S1410* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as COSV100956545; called by muse, mutect2, varscan2
- BSN | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99609858; called by muse, mutect2, varscan2
- BSN | c.11171G>A p.G3724D | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV99609859; called by muse, mutect2, varscan2
- BTNL9 | c.242A>G p.N81S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV100576273; called by muse, mutect2, varscan2
- C11orf53 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV99724908; called by muse, mutect2, varscan2
- C19orf57 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.224); catalogued as COSV100694855; called by muse, mutect2, varscan2
- C6orf118 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as rs796728376, COSV100025162; called by muse, mutect2, varscan2
- CA7 | c.632G>A p.W211* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV100623819; called by muse, mutect2, varscan2
- CABS1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99909210; called by muse, mutect2, varscan2
- CACNA1B | c.3146A>G p.Q1049R | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs774321588, COSV99499867; called by muse, varscan2
- CACNA1H | c.6530C>T p.P2177L | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs774592173, COSV52357461, COSV99327086; called by muse, mutect2, varscan2
- CACNA2D2 | c.2648T>C p.V883A (on ENST00000479441 / NM_001174051.3; = p.V876A on NM_006030.4) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV99818364; called by muse, mutect2, varscan2
- CACNA2D2 | c.405G>A p.K135= | Splice Region (SNP) | VAF 41/111 reads (37%) | catalogued as COSV99818365; called by muse, mutect2, varscan2
- CACNA2D3 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV55549762, COSV99877150; called by muse, mutect2, varscan2
- CAD | c.6442C>T p.Q2148* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99255748; called by muse, mutect2, varscan2
- CAMSAP3 | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV50347163; called by muse, mutect2, varscan2
- CARM1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100499094; called by muse, mutect2, varscan2
- CARM1 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs776086779, COSV100499095; called by muse, mutect2, varscan2
- CBLL1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1309188215, COSV99755956; called by muse, mutect2, varscan2
- CCDC74A | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99723928; called by muse, mutect2, varscan2
- CCNF | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV99564171; called by muse, mutect2, varscan2
- CD200R1 | c.358C>T p.R120C (on ENST00000471858 / NM_170780.3; = p.R143C on NM_138806.4) | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1176485330, COSV55605443; called by muse, mutect2, varscan2
- CD9 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs752203680, COSV99153227; called by muse, mutect2, varscan2
- CD93 | c.1675C>T p.Q559* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as rs373765657, COSV55663718; called by muse, mutect2, varscan2
- CDH6 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); catalogued as COSV99420851; called by muse, mutect2, varscan2
- CDH8 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs1055288839, COSV54849423; called by muse, mutect2, varscan2
- CDKL3 | c.1205C>T p.T402I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99528147; called by muse, mutect2, varscan2
- CEACAM20 | c.1722G>A p.M574I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100387034; called by muse, mutect2, varscan2
- CELSR1 | c.4448G>A p.G1483D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53082801; called by muse, mutect2, varscan2
- CENPI | c.1631C>T p.S544F | Missense Mutation (SNP) | VAF 52/67 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99515832; called by muse, mutect2, varscan2
- CFAP43 | c.3414G>A p.M1138I | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.19); catalogued as COSV100829478; called by muse, mutect2, varscan2
- CFAP54 | c.6304G>A p.G2102R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.054); catalogued as rs776874180, COSV100733338; called by muse, mutect2, varscan2
- CFH | c.1226G>A p.G409D | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.923); catalogued as COSV100661645, COSV62778771; called by muse, mutect2, varscan2
- CFHR1 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs750501937, COSV100259003; called by muse, mutect2, varscan2
- CGNL1 | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); catalogued as COSV99849166; called by muse, mutect2, varscan2
- CHAT | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.904); catalogued as rs774834313, COSV60334614; called by muse, mutect2, varscan2
- CHRNA1 | c.1061C>T p.P354L (on ENST00000261007 / NM_001039523.3; = p.P329L on NM_000079.4) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99650723; called by muse, mutect2, varscan2
- CIPC | c.812G>C p.S271T | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.503); catalogued as COSV100694495, COSV62376968; called by muse, mutect2, varscan2
- CLCA2 | c.2169G>A p.M723I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100991739; called by muse, mutect2, varscan2
- CLCA4 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99760204, COSV99760826; called by muse, mutect2, varscan2
- CLEC17A | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV60429837; called by muse, mutect2, varscan2
- CLEC5A | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 97/120 reads (81%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as COSV101407800; called by muse, mutect2, varscan2
- CLGN | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as rs773210960, COSV100346823; called by muse, mutect2, varscan2
- CLGN | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100346825, COSV57775802; called by muse, mutect2, varscan2
- CLIP4 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs139683869; called by muse, mutect2, varscan2
- CLTCL1 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV99595888; called by muse, mutect2, varscan2
- CLVS2 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.605); catalogued as COSV51562421; called by muse, mutect2, varscan2
- CMYA5 | c.9697G>A p.G3233R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV71411007; called by muse, mutect2, varscan2
- CNKSR1 | c.1546G>A p.E516K (on ENST00000374253 / NM_001297647.2; = p.E509K on NM_006314.3) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58792732; called by muse, mutect2, varscan2
- CNKSR3 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV101401413; called by muse, mutect2, varscan2
- CNNM1 | c.2650C>T p.P884S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs773788510, COSV100763990; called by muse, varscan2
- CNTN5 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.702); catalogued as COSV54309438; called by muse, mutect2, varscan2
- CNTN5 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757785890, COSV54352345; called by muse, mutect2, varscan2
- COL10A1 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99684469; called by muse, mutect2, varscan2
- COL12A1 | c.8773C>T p.Q2925* | Nonsense Mutation (SNP) | VAF 46/219 reads (21%) | catalogued as COSV100486547; called by muse, mutect2, varscan2
- COL12A1 | c.7193G>A p.G2398E | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59396466; called by muse, mutect2, varscan2
- COL15A1 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV100897823; called by muse, mutect2, varscan2
- COL20A1 | c.2201A>C p.Y734S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV100491449; called by muse, mutect2
- COL4A2 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100847485; called by muse, mutect2, varscan2
- COL4A4 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs762822768, COSV61633794; called by muse, mutect2, varscan2
- COL4A4 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV61630157; called by muse, mutect2, varscan2
- COL5A1 | c.4124G>A p.G1375E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100880589; called by muse, mutect2, varscan2
- COL5A3 | c.3536C>T p.P1179L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99319778; called by muse, mutect2, varscan2
- COL5A3 | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99319781; called by muse, mutect2
- COL6A6 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as rs762659584, COSV62027926; called by muse, mutect2, varscan2
- COL8A2 | c.1960G>A p.G654S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV100291397; called by muse, mutect2, varscan2
- COLEC10 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.354); catalogued as COSV100250915; called by muse, mutect2, varscan2
- COP1 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58172414; called by muse, mutect2, varscan2
- CORO1A | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV99532204; called by muse, mutect2, varscan2
- CPEB3 | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV56454301; called by muse, mutect2
- CPSF6 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as COSV99879681; called by muse, mutect2, varscan2
- CRISP1 | c.-2G>A | Splice Region (SNP) | VAF 11/36 reads (31%) | catalogued as rs764192737, COSV100237102; called by muse, mutect2, varscan2
- CRISP3 | c.391C>T p.L131F (on ENST00000371159 / NM_001368123.1; = p.L113F on NM_006061.4) | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53820389; called by muse, mutect2, varscan2
- CRNKL1 | c.1904T>C p.F635S | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV101057142; called by muse, mutect2, varscan2
- CRYBA4 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100697863; called by muse, mutect2, varscan2
- CRYBG1 | c.3433G>A p.E1145K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765446944, COSV100954381; called by muse, mutect2, varscan2
- CSMD2 | c.9161G>A p.G3054E | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); catalogued as rs867595146, COSV53878837; called by muse, mutect2, varscan2
- CXCR1 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV55282771; called by muse, mutect2, varscan2
- CYFIP2 | c.3196C>G p.R1066G (on ENST00000616178 / NM_001291722.2; = p.R1041G on NM_014376.4) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.16); catalogued as COSV100557783, COSV59034515; called by muse, mutect2, varscan2
- CYP2E1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.648); catalogued as rs138223492; called by muse, mutect2, varscan2
- DCC | c.2155G>A p.D719N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100503115, COSV59112147; called by muse, mutect2, varscan2
- DCC | c.3287G>A p.S1096N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV101473549; called by mutect2, varscan2
- DCDC1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs192206218, COSV60837276; called by muse, mutect2, varscan2
- DDIT4 | c.229T>C p.S77P | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as COSV100259187; called by muse, mutect2, varscan2
- DEK | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV55236662, COSV99789148; called by muse, mutect2, varscan2
- DIXDC1 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101098862; called by muse, mutect2
- DLEU7 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.947); catalogued as rs753989174, COSV101246937; called by muse, varscan2
- DNAH1 | c.6083C>T p.P2028L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV101327080; called by muse, mutect2, varscan2
- DNAH11 | c.5296G>A p.E1766K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs371235859, COSV100177434; ClinVar: uncertain significance; called by muse, mutect2
- DNAH5 | c.13774C>T p.R4592* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as rs758112779, COSV54210253, COSV54253592, COSV99455552; called by muse, mutect2, varscan2
- DNAH5 | c.9530C>T p.S3177L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54246092; called by muse, mutect2, varscan2
- DNAH8 | c.5563A>G p.T1855A | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100547244; called by muse, mutect2, varscan2
- DNASE1L3 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV100568854; called by muse, mutect2, varscan2
- DNM3 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs201627857; called by muse, mutect2, varscan2
- DOCK11 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 50/62 reads (81%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV99354748; called by muse, mutect2, varscan2
- DPPA4 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100169715; called by muse, mutect2, varscan2
- DSC2 | c.2038C>T p.R680C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs757253682, COSV51870668; called by muse, mutect2, varscan2
- DSCAM | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as rs267606128, COSV68029375; called by muse, mutect2, varscan2
- DSCAM | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV101260802, COSV68024922; called by muse, mutect2, varscan2
- DSE | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs866075089, COSV59062855; called by muse, mutect2, varscan2
- DSG4 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759072801, COSV57396819; called by muse, mutect2, varscan2
- DYNC1I1 | c.1104G>A p.W368* | Nonsense Mutation (SNP) | VAF 31/95 reads (33%) | catalogued as rs913296254, COSV61457640; called by muse, mutect2, varscan2
- DYNC1LI2 | c.859A>G p.I287V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV99263275; called by muse, mutect2, varscan2
- DYSF | c.4130A>G p.N1377S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.755); catalogued as COSV99250421; called by muse, mutect2, varscan2
- EBF1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs759525156, COSV100566611; called by muse, mutect2, varscan2
- EEA1 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as rs746414988, COSV59284324; called by muse, mutect2, varscan2
- EHMT1 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100604280; called by muse, mutect2, varscan2
- EIF3B | c.1109G>A p.R370K | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV100703862; called by muse, mutect2, varscan2
- ELOVL2 | c.168G>A p.M56I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100676088; called by muse, mutect2, varscan2
- ENAM | c.3176G>A p.G1059D | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as COSV101253340; called by muse, mutect2, varscan2
- ENPEP | c.2794G>A p.V932M | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99488148; called by muse, mutect2, varscan2
- EP400 | c.4318C>T p.R1440C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1473681078, COSV57770284; called by muse, mutect2, varscan2
- EPG5 | c.1753C>T p.H585Y | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV99958121; called by muse, mutect2, varscan2
- EPHA4 | c.2845G>A p.E949K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV99917512; called by muse, mutect2, varscan2
- EPHA7 | c.2983G>A p.G995S | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV100994361; called by muse, mutect2, varscan2
- EPHB2 | c.2132T>A p.L711H (on ENST00000400191 / NM_001309193.2; = p.L712H on NM_004442.7) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101007390; called by muse, mutect2, varscan2
- EPOR | c.1007A>C p.E336A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99710312; called by muse, mutect2, varscan2
- EQTN | c.289+1G>A p.X97_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV101192409; called by muse, mutect2, varscan2
- ERBB4 | c.2924C>T p.S975L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV61512047; called by muse, mutect2, varscan2
- EREG | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs866675158, COSV55260744; called by muse, mutect2, varscan2
- ERICH6 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV99901999; called by muse, mutect2, varscan2
- EVC2 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.104); catalogued as COSV100186924; called by muse, mutect2, varscan2
- EXOC4 | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1281443973, COSV99555765; called by muse, mutect2, varscan2
- FAAP100 | c.2273C>T p.A758V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1244921173, COSV100585599; called by muse, mutect2
- FABP2 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370366662; called by muse, mutect2, varscan2
- FAM135B | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99060072, COSV99427617; called by muse, mutect2, varscan2
- FAM135B | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV52725538, COSV52758416; called by muse, mutect2, varscan2
- FAM151A | c.800G>A p.R267K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as COSV100157120; called by muse, mutect2
- FAM170A | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV100089336; called by muse, mutect2, varscan2
- FAM47B | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 51/69 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV100264644; called by muse, mutect2, varscan2
- FAM76A | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV99159694; called by muse, mutect2, varscan2
- FAM90A1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.655); catalogued as rs750289614, COSV56715116; called by muse, mutect2, varscan2
- FANCC | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776991402, COSV100003069; called by muse, mutect2, varscan2
- FARP1 | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs149379616, COSV60339792; called by muse, mutect2, varscan2
- FAT3 | c.12629G>A p.R4210Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs367816972, COSV53073963; called by muse, mutect2, varscan2
- FAT4 | c.11332C>T p.P3778S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV58675914; called by muse, mutect2, varscan2
- FAT4 | c.12629C>T p.S4210L | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58702376; called by muse, mutect2, varscan2
- FBLN5 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99969451; called by muse, mutect2, varscan2
- FBN3 | c.7978G>A p.D2660N | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99561850; called by muse, mutect2, varscan2
- FCRL5 | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as COSV100709326; called by muse, mutect2, varscan2
- FEN1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145709748; called by muse, mutect2, varscan2
- FER1L6 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV101206198; called by muse, mutect2, varscan2
- FERMT1 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs760234003, COSV99452161; called by muse, mutect2, varscan2
- FGFR1 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.83); catalogued as COSV100249259; called by muse, mutect2
- FLG | c.3763G>A p.E1255K | Missense Mutation (SNP) | VAF 94/326 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV64245911; called by muse, mutect2, varscan2
- FLRT1 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.86); PolyPhen benign (0.077); catalogued as COSV99736145; called by muse, mutect2, varscan2
- FMN2 | c.3884C>T p.P1295L | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327176883, COSV100147132; called by muse, mutect2, varscan2
- FMO1 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs1373403105, COSV100707947; called by muse, mutect2, varscan2
- FOXP1 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); catalogued as rs752297898, COSV59524063; called by muse, mutect2, varscan2
- FRY | c.8279C>T p.A2760V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as COSV100969924; called by muse, mutect2, varscan2
- FZD10 | c.656G>A p.W219* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99969605; called by muse, mutect2, varscan2
- GABRA3 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 35/39 reads (90%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100943443; called by muse, mutect2, varscan2
- GABRE | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 64/82 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64818853; called by muse, mutect2, varscan2
- GALNT6 | c.1846C>T p.H616Y | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV100695667; called by muse, mutect2, varscan2
- GATAD2A | c.1799G>A p.S600N | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.388); catalogued as COSV99390726; called by muse, mutect2, varscan2
- GGT6 | c.317A>C p.H106P | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as COSV99626964; called by muse, varscan2
- GGT6 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99626968; called by muse, mutect2, varscan2
- GHR | c.608A>T p.K203I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.138); catalogued as COSV100052036; called by muse, mutect2, varscan2
- GIMAP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 42/62 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100212318; called by muse, mutect2, varscan2
- GINM1 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100805372; called by muse, mutect2, varscan2
- GIPC3 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.388); catalogued as COSV59260001; called by muse, mutect2, varscan2
- GLCCI1 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56204125; called by muse, mutect2, varscan2
- GLI2 | c.4454C>T p.S1485F (on ENST00000361492 / NM_001374353.1; = p.S1502F on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100084337; called by muse, mutect2, varscan2
- GLYAT | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV53540529; called by muse, mutect2, varscan2
- GOLIM4 | c.1117A>G p.K373E | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV100463479; called by muse, mutect2, varscan2
- GPRC6A | c.2494C>T p.P832S | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100114780; called by muse, mutect2, varscan2
- GRID2 | c.2891C>T p.P964L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99946906; called by muse, mutect2, varscan2
- GRM3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/87 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV100862386, COSV64466579; called by muse, mutect2, varscan2
- GRM6 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV51440060, COSV99179948; called by muse, mutect2, varscan2
- GRXCR1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV67670829; called by muse, mutect2, varscan2
- GRXCR1 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV67674524; called by muse, mutect2, varscan2
- GSK3B | c.597T>A p.C199* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99955695; called by muse, mutect2, varscan2
- GSTA1 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100575612; called by muse, mutect2, varscan2
- GUCY1A2 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV56507617; called by muse, mutect2, varscan2
- GYPB | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as rs757106926, COSV51621678; called by muse, mutect2, varscan2
- GYS2 | c.379C>A p.L127M | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99680259; called by muse, mutect2, varscan2
- HBG2 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57964566; called by muse, mutect2, varscan2
- HCN1 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 38/111 reads (34%) | catalogued as COSV57491564; called by muse, mutect2, varscan2
- HEATR6 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1009633403, COSV51748451; called by muse, mutect2, varscan2
- HECTD1 | c.1409G>A p.R470K | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV101237518; called by muse, mutect2, varscan2
- HECW2 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV99649056; called by muse, mutect2, varscan2
- HEPHL1 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV59889262; called by mutect2, varscan2
- HGF | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV55947254; called by muse, mutect2, varscan2
- HHLA2 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.441); catalogued as COSV63316142; called by muse, mutect2, varscan2
- HIVEP2 | c.5113T>C p.Y1705H | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99175498; called by muse, mutect2, varscan2
- HIVEP3 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV99914007; called by muse, mutect2, varscan2
- HOXD12 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs1184526781, COSV101184352; called by muse, mutect2, varscan2
- HS3ST4 | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100503084; called by muse, mutect2, varscan2
- HSP90AA1 | c.1993T>G p.L665V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99355523; called by muse, mutect2
- HSPG2 | c.8111C>T p.A2704V | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.752); catalogued as COSV101021248; called by muse, mutect2, varscan2
- HTR3A | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.851); catalogued as COSV100248623; called by muse, mutect2, varscan2
- HTR4 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); catalogued as rs199912477, COSV58804814; called by muse, mutect2, varscan2
- HYDIN | c.9917G>A p.R3306Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs578231783, COSV66863806; called by muse, mutect2, varscan2
- HYOU1 | c.1601A>G p.Y534C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.796); catalogued as rs1007553493, COSV101345675; called by muse, mutect2, varscan2
- IGHV3-73 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.796); catalogued as rs760460589; called by muse, mutect2, varscan2
- IGKV1-16 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 44/132 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.076); catalogued as rs766218057; called by muse, mutect2, varscan2
- IGSF1 | c.2220G>C p.M740I | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV100812335; called by muse, mutect2, varscan2
- IGSF3 | c.1478C>T p.S493L (on ENST00000369486 / NM_001007237.3; = p.S513L on NM_001542.4) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.91); catalogued as rs752167211, COSV59598319; called by muse, mutect2, varscan2
- IKZF1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV58782463; called by muse, mutect2, varscan2
- IL27RA | c.1592G>A p.G531E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs1202978526, COSV99652383; called by muse, mutect2, varscan2
- IL5RA | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV56523375; called by muse, mutect2, varscan2
- IL6ST | c.2563C>T p.H855Y | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV100411052; called by muse, mutect2, varscan2
- IL7R | c.792G>A p.W264* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV57405450, COSV57405806; called by muse, mutect2, varscan2
- ILDR1 | c.1072C>T p.P358S (on ENST00000344209 / NM_001199799.2; = p.P314S on NM_175924.4) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56546926; called by muse, mutect2, varscan2
- IMPG1 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as COSV64058379; called by muse, mutect2, varscan2
- IMPG1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64057964; called by muse, mutect2, varscan2
- INPP5D | c.2305G>A p.E769K (on ENST00000445964 / NM_001017915.3; = p.E768K on NM_005541.5) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1190861454, COSV100856926; called by muse, mutect2
- INTS7 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100877577; called by muse, mutect2, varscan2
- IPO5 | c.1717-2A>T p.X573_splice | Splice Site (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99847681; called by muse, mutect2, varscan2
- IPO9 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1216836571, COSV100843572; called by muse, mutect2, varscan2
- ISOC2 | c.349-5C>A | Splice Region (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99321351; called by muse, mutect2, varscan2
- ITGB1BP2 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV99339139; called by muse, mutect2, varscan2
- ITIH5 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs768083133, COSV53661083; called by muse, mutect2, varscan2
- JCAD | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.085); catalogued as COSV100948576; called by muse, mutect2, varscan2
- JPH1 | c.1140-1G>A p.X380_splice | Splice Site (SNP) | VAF 11/22 reads (50%) | catalogued as COSV100646786; called by muse, mutect2, varscan2
- KALRN | c.2590T>G p.L864V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV53756621; called by muse, mutect2, varscan2
- KBTBD12 | c.1210A>G p.N404D | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.193); catalogued as COSV100675529; called by muse, mutect2, varscan2
- KCNB2 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated, low confidence (0.51); PolyPhen probably damaging (0.999); catalogued as rs774227848, COSV101579006, COSV73053532; called by muse, mutect2, varscan2
- KCND3 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.894); catalogued as COSV56175092; called by muse, mutect2, varscan2
- KCNH1 | c.1874C>T p.S625F (on ENST00000271751 / NM_172362.3; = p.S598F on NM_002238.4) | Missense Mutation (SNP) | VAF 78/133 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99661511; called by muse, mutect2, varscan2
- KCNH8 | c.2915G>A p.R972Q | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.407); catalogued as rs563622438, COSV60456968; called by muse, mutect2, varscan2
- KCNIP1 | c.419G>A p.W140* (on ENST00000411494 / NM_001034837.3; = p.W129* on NM_014592.4) | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100200106; called by muse, mutect2, varscan2
- KCNIP1 | c.420G>A p.W140* (on ENST00000411494 / NM_001034837.3; = p.W129* on NM_014592.4) | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as rs1561784284, COSV100200108; called by muse, mutect2, varscan2
- KCNJ13 | c.564C>G p.I188M | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99289399; called by muse, mutect2, varscan2
- KCNQ3 | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1563761224, COSV66464416; called by muse, mutect2, varscan2
- KCNQ3 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66483195; called by muse, mutect2, varscan2
- KCNS3 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs556337820, COSV100411104; called by muse, mutect2, varscan2
- KDM6B | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.605); catalogued as COSV99642305; called by muse, mutect2, varscan2
- KHDRBS2 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV55502335; called by muse, mutect2
- KIAA0319 | c.2318G>A p.S773N | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.412); catalogued as COSV100985812; called by muse, mutect2, varscan2
- KIAA1109 | c.10228C>T p.H3410Y | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99165249; called by muse, mutect2, varscan2
- KIAA1549L | c.2587C>T p.H863Y (on ENST00000321505; = p.H1160Y on NM_012194.3) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV55781589, COSV99683495; called by muse, mutect2, varscan2
- KIF18A | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV99589119; called by muse, mutect2, varscan2
- KIF21B | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as COSV100144115; called by muse, mutect2, varscan2
- KIF21B | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100145154; called by muse, mutect2, varscan2
- KLHDC7A | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1553122963, COSV68769075; called by muse, mutect2, varscan2
- KLHL5 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs757541285, COSV99785138; called by muse, mutect2, varscan2
- KMT2C | c.8095C>A p.L2699M | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV100076515; called by muse, mutect2, varscan2
- KREMEN1 | c.347-1G>T p.X116_splice (on ENST00000407188; = p.X118_splice on NM_032045.5) | Splice Site (SNP) | VAF 26/77 reads (34%) | catalogued as COSV100588818; called by muse, mutect2, varscan2
- KRI1 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs767219440, COSV57264290; called by muse, mutect2, varscan2
- KRT38 | c.495C>T p.I165= | Splice Region (SNP) | VAF 22/55 reads (40%) | catalogued as rs1295869884, COSV99878394; called by muse, mutect2, varscan2
- KRT4 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV99543220; called by muse, mutect2, varscan2
- KRT6C | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV99360199; called by muse, mutect2, varscan2
- KRT7 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV99230236; called by muse, mutect2, varscan2
- KRTAP19-5 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs761275320, COSV61859800; called by muse, mutect2, varscan2
- LAMA2 | c.3107C>T p.T1036I | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101370835; called by muse, mutect2, varscan2
- LAMA2 | c.7745G>A p.G2582E | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); catalogued as COSV101370836; called by muse, mutect2, varscan2
- LARP4 | c.461T>C p.I154T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99529689; called by muse, mutect2, varscan2
- LAX1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV65849171; called by muse, mutect2, varscan2
- LEAP2 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs150053880; called by muse, mutect2, varscan2
- LILRB2 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.523); catalogued as COSV100079655; called by muse, mutect2, varscan2
- LIMCH1 | c.1166G>A p.R389K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs1398533388, COSV100574419; called by muse, mutect2, varscan2
- LMX1A | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99673191; called by muse, mutect2, varscan2
- LNPK | c.114A>T p.L38F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV99770477; called by muse, mutect2, varscan2
- LRFN2 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100599945; called by muse, mutect2, varscan2
- LRP1B | c.11051C>T p.S3684F | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.876); catalogued as COSV101261093, COSV104432040; called by muse, mutect2, varscan2
- LRP1B | c.10792G>A p.E3598K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101261094; called by muse, mutect2, varscan2
- LRP1B | c.7621G>A p.D2541N | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101261095; called by muse, mutect2, varscan2
- LRP2 | c.11294G>A p.R3765Q | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.936); catalogued as rs9646779; called by muse, mutect2, varscan2
- LRRC8C | c.88T>A p.Y30N | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100968436; called by muse, mutect2, varscan2
- LRRN1 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as rs1300200167, COSV60012895; called by muse, mutect2, varscan2
- LTF | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as COSV99211805; called by muse, mutect2, varscan2
- LUC7L3 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV99537199; called by muse, mutect2, varscan2
- LY9 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.362); catalogued as COSV99627463; called by muse, mutect2, varscan2
- MAGEB1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 40/45 reads (89%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as COSV66775620; called by muse, mutect2, varscan2
- MAGEB18 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.936); catalogued as COSV57463376, COSV57465510; called by muse, mutect2, varscan2
- MAGI2 | c.2175G>T p.R725S | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as COSV100836608; called by muse, mutect2, varscan2
- MAP3K4 | c.2540C>T p.S847L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV100815684; called by muse, mutect2, varscan2
- MAP3K9 | c.446T>A p.I149N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101173763; called by muse, mutect2, varscan2
- MARCHF11 | c.914T>C p.V305A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100198272; called by muse, mutect2, varscan2
- MAST4 | c.4240C>T p.P1414S (on ENST00000403625 / NM_001164664.2; = p.P1225S on NM_015183.3) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99845886; called by muse, mutect2, varscan2
- MDC1 | c.-1C>T | Splice Region (SNP) | VAF 25/70 reads (36%) | catalogued as COSV100903087; called by muse, mutect2, varscan2
- MDH2 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as rs1554585973, COSV100242812; called by muse, mutect2, varscan2
- MDN1 | c.9381C>T p.F3127= | Splice Region (SNP) | VAF 11/48 reads (23%) | catalogued as COSV101021832; called by muse, mutect2, varscan2
- MECOM | c.169G>A p.D57N (on ENST00000468789 / NM_001105078.4; = p.D245N on NM_004991.4) | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as COSV99245437; called by muse, mutect2, varscan2
- MEFV | c.2210G>A p.R737K | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs139092123; called by muse, mutect2, varscan2
- MFAP5 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866733609, COSV63945409; called by muse, mutect2, varscan2
- MFNG | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.247); catalogued as rs200159869, COSV100812947; called by muse, mutect2, varscan2
- MGA | c.7138C>T p.P2380S (on ENST00000219905 / NM_001164273.1; = p.P2171S on NM_001080541.2) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV99581569; called by muse, mutect2, varscan2
- MICALL2 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV99876274; called by muse, mutect2, varscan2
- MKI67 | c.9269C>A p.S3090Y | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs747505583, COSV100896994; called by muse, mutect2, varscan2
- MKI67 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV100896995; called by muse, mutect2, varscan2
- MKKS | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100726320; called by muse, mutect2, varscan2
- MLANA | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101199968; called by muse, mutect2, varscan2
- MPHOSPH9 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as COSV56625144; called by muse, mutect2, varscan2
- MPO | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs918010451, COSV99833031; called by muse, mutect2
- MRC2 | c.2537G>A p.W846* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100316783; called by muse, mutect2, varscan2
- MRC2 | c.2538G>A p.W846* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100316785; called by muse, mutect2, varscan2
- MROH2B | c.3133C>T p.Q1045* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV101270925; called by muse, mutect2, varscan2
- MRPL11 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs753120646, COSV100207874, COSV60599698; called by muse, mutect2, varscan2
- MRPL13 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.056); catalogued as rs781110831, COSV60369251; called by muse, mutect2, varscan2
- MSH6 | c.1589A>T p.D530V | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV99316946; called by muse, mutect2, varscan2
- MTCL1 | c.1880C>T p.S627F (on ENST00000306329 / NM_001378206.1; = p.S267F on NM_015210.4) | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs746517189, COSV100095588; called by muse, mutect2, varscan2
- MUC16 | c.43085G>A p.R14362Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); catalogued as rs1215833683, COSV101110091; called by muse, mutect2, varscan2
- MUC16 | c.36656G>A p.S12219N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.089); catalogued as COSV101201732; called by muse, mutect2, varscan2
- MUC16 | c.35332C>T p.P11778S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as COSV67503035; called by muse, mutect2, varscan2
- MUC16 | c.25658C>T p.P8553L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs767985132, COSV67444917, COSV67488259; called by muse, mutect2, varscan2
- MUC16 | c.23402C>T p.S7801F | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as COSV101201733; called by muse, mutect2, varscan2
- MUC16 | c.20894C>T p.S6965F | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); catalogued as COSV67495406; called by muse, mutect2, varscan2
- MUC16 | c.15701C>T p.S5234F | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV67445111; called by muse, mutect2, varscan2
- MUC4 | c.1948C>A p.Q650K | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.044); catalogued as rs918259859, COSV100642311; called by muse, mutect2, varscan2
- MUC5AC | c.16204G>A p.E5402K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as rs1326327218, COSV100611350; called by muse, mutect2, varscan2
- MUC5B | c.12083G>A p.W4028* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV101500766; called by muse, mutect2, varscan2
- MUSK | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.08); catalogued as COSV99505150; called by muse, mutect2, varscan2
- MUSK | c.2038C>A p.H680N | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.047); catalogued as COSV99505151; called by muse, varscan2
- MUSK | c.2077G>T p.G693W | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV99505154; called by muse, varscan2
- MUSK | c.2594G>A p.G865E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs750132076, COSV51896866; called by muse, mutect2, varscan2
- MYBPC1 | c.3026A>G p.N1009S (on ENST00000550270 / NM_206820.2; = p.N1016S on NM_002465.4) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100638286; called by muse, mutect2, varscan2
- MYCN | c.36G>A p.M12I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.157); catalogued as COSV99808552; called by muse, mutect2, varscan2
- MYH15 | c.3385G>A p.D1129N | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56306147, COSV56309268; called by muse, mutect2
- MYH2 | c.5222C>T p.S1741F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV55442525; called by muse, mutect2, varscan2
- MYH8 | c.5014G>A p.E1672K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs1203414443, COSV67975385; called by muse, mutect2, varscan2
- MYH8 | c.4885G>A p.E1629K | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101238796; called by muse, mutect2, varscan2
- MYLK3 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101189220; called by muse, mutect2, varscan2
- MYO15A | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV99234432; called by muse, mutect2, varscan2
- MYRIP | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV100220024; called by muse, mutect2, varscan2
- N4BP2 | c.2197A>T p.N733Y | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV99789289; called by muse, mutect2, varscan2
- NAV3 | c.4976C>T p.P1659L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.103); catalogued as COSV57078606; called by muse, mutect2, varscan2
- NBEAL2 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs1301587734, COSV99437636; called by muse, mutect2, varscan2
- NCAPD2 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 96/184 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs756503239, COSV100217447; called by muse, mutect2, varscan2
- NDE1 | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV100707344; called by muse, mutect2, varscan2
- NEB | c.3461A>C p.D1154A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.998); catalogued as rs727504036, COSV99428048; called by muse, mutect2, varscan2
- NES | c.4388T>G p.V1463G | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV100957997; called by muse, mutect2, varscan2
- NEURL4 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV59761748; called by muse, mutect2, varscan2
- NFX1 | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100582462; called by muse, mutect2, varscan2
- NGFR | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as rs1375230160, COSV99413067; called by muse, mutect2
- NHLRC2 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs867268865, COSV100993028; called by muse, mutect2, varscan2
- NIBAN1 | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100836629; called by muse, mutect2, varscan2
- NLN | c.1713A>C p.T571= | Splice Region (SNP) | VAF 17/45 reads (38%) | catalogued as COSV101114484; called by muse, mutect2, varscan2
- NLRP11 | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs141366900; called by muse, mutect2, varscan2
- NLRP11 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415271061, COSV100789815; called by muse, mutect2, varscan2
- NLRP12 | c.2000G>A p.G667D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.582); catalogued as rs1394707799, COSV100145928; called by muse, mutect2, varscan2
- NLRP4 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56708963; called by muse, mutect2, varscan2
- NLRP7 | c.2326G>A p.E776K (on ENST00000340844 / NM_206828.3; = p.E748K on NM_139176.3) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1340954076, COSV60173901; called by muse, mutect2, varscan2
- NLRP8 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as rs867849674, COSV52583835; called by muse, mutect2, varscan2
- NMUR1 | c.940C>T p.H314Y | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100532166; called by muse, mutect2, varscan2
- NOL8 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100694696; called by muse, mutect2, varscan2
- NOP14 | c.1961_1962del p.E654Gfs*17 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | catalogued as rs752663755; called by pindel, varscan2
- NOS1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100501421; called by muse, mutect2, varscan2
- NOS1 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as rs559110279, COSV100501422; called by muse, mutect2, varscan2
- NPAP1 | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.23); catalogued as rs947703227, COSV100276203; called by muse, mutect2, varscan2
- NPAS4 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.992); catalogued as rs1209500056, COSV100215265; called by muse, mutect2, varscan2
- NR1D1 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99225797; called by muse, mutect2, varscan2
- NR5A2 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV52644215; called by muse, mutect2, varscan2
- NUMB | c.1427C>T p.S476F (on ENST00000355058; = p.S465F on NM_003744.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV99390456; called by muse, mutect2, varscan2
- NUP98 | c.3175C>T p.L1059F (on ENST00000359171 / NM_001365126.1; = p.L1042F on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100263480; called by muse, mutect2, varscan2
- NYAP2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as rs1207374088, COSV55998910; called by muse, mutect2
- NYNRIN | c.3811G>A p.E1271K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV101230702; called by muse, mutect2, varscan2
- OBSCN | c.10786C>T p.R3596C | Missense Mutation (SNP) | VAF 110/220 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as rs780249455, COSV52735779, COSV52799230; called by muse, mutect2, varscan2
- OIT3 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs774831409, COSV100468006, COSV61826742; called by muse, mutect2, varscan2
- OR1A2 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101126390; called by muse, mutect2, varscan2
- OR1L8 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1289473167, COSV100508683; called by muse, mutect2, varscan2
- OR51A7 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs145773250, COSV63789095; called by muse, mutect2, varscan2
- OR51B5 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV100332682, COSV56176784; called by muse, mutect2, varscan2
- OR51B6 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV66514056; called by muse, mutect2
- OR51E2 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67807777; called by muse, mutect2, varscan2
- OR51F1 | c.454C>T p.Q152* | Nonsense Mutation (SNP) | VAF 24/65 reads (37%) | catalogued as COSV100598912; called by muse, mutect2
- OR51S1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV100437589; called by muse, mutect2, varscan2
- OR51V1 | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866961237, COSV58315699; called by muse, mutect2, varscan2
- OR52E6 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100259315; called by muse, mutect2, varscan2
- OR52E8 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs551753112, COSV101190402, COSV66207529; called by muse, mutect2, varscan2
- OR52M1 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100798617; called by muse, mutect2, varscan2
- OR52N1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV100398730; called by muse, mutect2, varscan2
- OR56A1 | c.444T>A p.S148R | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as COSV100360555; called by muse, mutect2, varscan2
- OR5H1 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs757618168, COSV100641776; called by muse, mutect2, varscan2
- OR5T2 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV100507084; called by muse, mutect2, varscan2
- OR5V1 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV65827182; called by muse, mutect2, varscan2
- OR6B1 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 73/96 reads (76%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs200084158; called by muse, mutect2, varscan2
- OR6F1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs1313686561, COSV57467720, COSV57467735; called by muse, mutect2, varscan2
- OR6N1 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV58649292; called by muse, mutect2, varscan2
- ORC5 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV99857410; called by muse, mutect2, varscan2
- OSMR | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs867485740, COSV57080986; called by muse, mutect2, varscan2
- P2RX3 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180051354, COSV99628947; called by muse, mutect2, varscan2
- P2RY1 | c.724A>G p.R242G | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV100521798; called by muse, mutect2, varscan2
- PACS2 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV57654756; called by muse, mutect2, varscan2
- PAK5 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.395); catalogued as COSV62035458; called by muse, mutect2, varscan2
- PAMR1 | c.1101G>A p.R367= (on ENST00000619888 / NM_001001991.3; = p.R384= on NM_015430.4) | Splice Region (SNP) | VAF 16/52 reads (31%) | catalogued as rs1401081114, COSV99553310; called by muse, mutect2
- PANK4 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753708600, COSV101022566; called by muse, mutect2, varscan2
- PAPLN | c.818C>T p.P273L (on ENST00000554301; = p.P246L on NM_173462.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99390450; called by muse, mutect2
- PAPPA2 | c.3347G>A p.G1116E | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100868653; called by muse, mutect2, varscan2
- PAPPA2 | c.3977A>T p.N1326I | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100868654; called by muse, mutect2, varscan2
- PCDH15 | c.4913A>C p.E1638A | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100227731; called by muse, mutect2, varscan2
- PCDH17 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV100932046, COSV64977266; called by muse, mutect2, varscan2
- PCDH9 | c.3341-1G>A p.X1114_splice (on ENST00000377865 / NM_203487.3; = p.X1080_splice on NM_020403.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100123569; called by muse, mutect2, varscan2
- PCLO | c.7895C>T p.P2632L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100437822; called by muse, mutect2, varscan2
- PCLO | c.4526C>T p.P1509L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100437826, COSV61649796; called by muse, mutect2, varscan2
- PCOLCE2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.067); catalogued as rs761462363, COSV55997270; called by muse, mutect2, varscan2
- PCSK5 | c.4952C>T p.S1651L | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as rs750832900, COSV101377709; called by muse, mutect2, varscan2
- PDE6D | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.303); catalogued as rs758019119, COSV99807914; called by muse, mutect2, varscan2
- PGK2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs780717653, COSV59162785; called by muse, mutect2, varscan2
- PGLYRP2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV99484298; called by muse, mutect2, varscan2
- PHF11 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.368); catalogued as COSV100710654; called by muse, mutect2, varscan2
- PHIP | c.3412C>T p.P1138S | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.253); catalogued as COSV51501777; called by muse, mutect2, varscan2
- PHKA1 | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs782021614, COSV59803683; called by muse, mutect2, varscan2
- PIF1 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.853); catalogued as COSV99165247; called by muse, mutect2, varscan2
- PIGN | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as COSV100716222, COSV62950860; called by muse, mutect2, varscan2
- PIK3R4 | c.447C>G p.I149M | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV63240941; called by muse, mutect2, varscan2
- PIP5K1C | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as rs773538890, COSV100096080, COSV58953603; called by muse, mutect2, varscan2
- PKHD1L1 | c.7418G>A p.R2473Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769741650, COSV65737397; called by mutect2, varscan2
- PKP2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 174/339 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99298494; called by muse, mutect2, varscan2
- PLAG1 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.506); catalogued as COSV57614809; called by muse, mutect2, varscan2
- PLCB4 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53803703; called by muse, mutect2, varscan2
- PLCL1 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101406822; called by muse, mutect2, varscan2
- PLCL2 | c.2777C>T p.P926L (on ENST00000615277 / NM_001144382.2; = p.P800L on NM_015184.5) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as COSV101197003; called by muse, mutect2, varscan2
- PLEKHG2 | c.2153C>T p.P718L | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs201459678, COSV99218112; called by muse, mutect2, varscan2
- PNPLA1 | c.700C>T p.P234S (on ENST00000394571 / NM_001374623.1; = p.P139S on NM_173676.2) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1457212883, COSV100463732; called by muse, mutect2, varscan2
- POLR1B | c.3065C>T p.T1022I | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99638556; called by muse, mutect2, varscan2
- POLR2G | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.788); catalogued as COSV100080183; called by muse, mutect2, varscan2
- POM121L12 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV101374983, COSV68692376; called by muse, mutect2, varscan2
- POP4 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.553); catalogued as COSV99694631; called by muse, mutect2, varscan2
- PPA2 | c.758C>T p.A253V (on ENST00000341695 / NM_176869.3; = p.A224V on NM_006903.4) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100500808; called by muse, mutect2, varscan2
- PPIC | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV100120639; called by muse, varscan2
- PPM1K | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759362568, COSV99901169; called by muse, mutect2, varscan2
- PRAMEF19 | c.1054C>T p.Q352* | Nonsense Mutation (SNP) | VAF 129/522 reads (25%) | catalogued as COSV65820704; called by muse, mutect2, varscan2
- PRDM16 | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200946004, COSV54578682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRG4 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.161); catalogued as COSV63355445; called by muse, mutect2, varscan2
- PRLR | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.374); catalogued as COSV99184784; called by muse, mutect2, varscan2
- PRLR | c.32T>C p.F11S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV99184787; called by muse, mutect2, varscan2
- PROSER1 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61486967; called by muse, mutect2, varscan2
- PRPF8 | c.3140T>G p.V1047G | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100517924; called by muse, mutect2, varscan2
- PRPSAP1 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99429705; called by muse, mutect2, varscan2
- PRRC2A | c.2296T>A p.S766T | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101051376; called by muse, mutect2, varscan2
- PRRC2B | c.6340C>T p.P2114S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV57644651; called by muse, mutect2, varscan2
- PRRC2C | c.5834C>T p.P1945L (on ENST00000367742; = p.P1943L on NM_015172.4) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs1256873943, COSV58902047; called by muse, mutect2, varscan2
- PRSS23 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99722587; called by muse, mutect2, varscan2
- PRSS38 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100816568; called by muse, mutect2, varscan2
- PSME4 | c.3130C>T p.H1044Y | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.391); catalogued as COSV101122655; called by muse, mutect2, varscan2
- PSMG2 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV100466694; called by muse, mutect2, varscan2
- PTBP2 | c.752T>C p.I251T (on ENST00000426398 / NM_001300986.2; = p.I243T on NM_021190.4) | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV100930285; called by muse, mutect2, varscan2
- PTK7 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV100030645; called by muse, mutect2, varscan2
- PTPRB | c.5329G>A p.G1777R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99718984; called by muse, varscan2
- PTPRB | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99718986; called by muse, mutect2, varscan2
- PTRH1 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs776316995, COSV100077095; called by muse, mutect2, varscan2
- PXDNL | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as rs1356811817, COSV62486477; called by muse, mutect2
- RAB35 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99984713; called by muse, mutect2, varscan2
- RANBP6 | c.2359G>C p.V787L | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV99424426; called by muse, mutect2, varscan2
- RASGRP3 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV101274902; called by muse, mutect2, varscan2
- RBFOX1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV60949051; called by muse, mutect2, varscan2
- RBM23 | c.479C>T p.P160L (on ENST00000359890 / NM_001077351.2; = p.P144L on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV100321526; called by muse, mutect2, varscan2
- RBM33 | c.1054C>T p.H352Y | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1290680369, COSV100265740; called by muse, mutect2, varscan2
- RBP7 | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV99606145; called by muse, mutect2, varscan2
- RBSN | c.1987C>T p.P663S | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99515541; called by muse, mutect2, varscan2
- RELN | c.7657C>T p.H2553Y | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.082); catalogued as COSV100634934; called by muse, mutect2, varscan2
- RFPL2 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV50710052; called by muse, mutect2, varscan2
- RGS6 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100667013; called by muse, mutect2, varscan2
- RGS8 | c.167C>T p.S56F (on ENST00000367556 / NM_001369564.2; = p.S74F on NM_033345.3) | Missense Mutation (SNP) | VAF 101/194 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51116018; called by muse, mutect2, varscan2
- RHBG | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54805559; called by muse, mutect2, varscan2
- ROBO2 | c.2560G>A p.D854N | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.655); catalogued as rs774444045, COSV100169957; called by muse, mutect2, varscan2
- ROPN1 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99481605; called by muse, mutect2, varscan2
- ROS1 | c.4616C>T p.P1539L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.071); catalogued as COSV100877458, COSV100877706; called by muse, mutect2, varscan2
- ROS1 | c.1781T>A p.I594N | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV100877707; called by muse, mutect2, varscan2
- RP1 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55118375; called by muse, mutect2, varscan2
- RP1 | c.2623G>A p.D875N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs775022086, COSV55112777, COSV55128982; called by muse, mutect2, varscan2
- RPRD1A | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as COSV59821520; called by muse, mutect2, varscan2
- RPS6KL1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV100665218; called by muse, mutect2, varscan2
- RSPH6A | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV99680113; called by muse, mutect2, varscan2
- RTL1 | c.3698G>A p.R1233Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); catalogued as rs866210313, COSV101128541; called by muse, mutect2, varscan2
- RYR2 | c.14528G>A p.R4843Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63676917; called by muse, mutect2, varscan2
- SAMD14 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99143101; called by muse, varscan2
- SAXO1 | c.122A>C p.Y41S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101000205; called by muse, mutect2, varscan2
- SCAF1 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV100862286; called by muse, mutect2, varscan2
- SCMH1 | c.1219C>T p.H407Y (on ENST00000326197 / NM_001031694.2; = p.H360Y on NM_012236.4) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV100402196; called by muse, mutect2, varscan2
- SCN10A | c.5587C>T p.R1863W | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370779258; called by muse, mutect2, varscan2
- SCN1A | c.753G>A p.M251I | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100322161; called by muse, mutect2, varscan2
- SCN9A | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202083986, COSV57599428; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCNN1D | c.1858G>A p.G620R (on ENST00000338555; = p.G784R on NM_001130413.4) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV100330276; called by muse, mutect2, varscan2
- SEC14L3 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs558774611, COSV53178776, COSV53179631; called by muse, mutect2, varscan2
- SEC23B | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111758941, COSV52718128; called by muse, mutect2, varscan2
- SEC24C | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100227158; called by muse, mutect2, varscan2
- SEMA3D | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs1309268425, COSV99405716; called by muse, mutect2, varscan2
- SERPINB7 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs1568207036, COSV100321037; called by muse, mutect2, varscan2
- SFRP2 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99923465; called by muse, mutect2, varscan2
- SFTPA1 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 71/283 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV100957198; called by muse, mutect2, varscan2
- SGSM1 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as COSV101241165; called by mutect2, varscan2
- SHBG | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100503142; called by muse, mutect2, varscan2
- SHROOM1 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.176); catalogued as rs1184227500, COSV100167290; called by muse, mutect2, varscan2
- SHROOM3 | c.2609G>A p.G870E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.113); catalogued as COSV99935357; called by muse, mutect2, varscan2
- SI | c.5168C>T p.S1723F | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV100017193; called by muse, mutect2, varscan2
- SIDT1 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as COSV53504825; called by muse, mutect2, varscan2
- SIGLEC10 | c.625C>T p.H209Y | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100219456, COSV59479706; called by muse, mutect2, varscan2
- SIRPB1 | c.933G>A p.W311* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV99498591; called by muse, mutect2, varscan2
- SLC12A5 | c.2569G>A p.D857N (on ENST00000454036 / NM_001134771.2; = p.D834N on NM_020708.5) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV99715751; called by muse, mutect2, varscan2
- SLC15A4 | c.1309C>T p.Q437* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99903641; called by muse, mutect2, varscan2
- SLC18B1 | c.215T>A p.I72N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV99259343; called by muse, mutect2, varscan2
- SLC26A9 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100536170, COSV100536779; called by muse, mutect2, varscan2
- SLC6A4 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99911609; called by muse, mutect2, varscan2
- SLC6A5 | c.2323G>A p.D775N | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.177); catalogued as rs776857479, COSV54223849; called by muse, mutect2, varscan2
- SLC7A14 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.598); catalogued as COSV99201017; called by muse, mutect2, varscan2
- SLITRK1 | c.1988C>T p.S663F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV65674498; called by muse, mutect2, varscan2
- SLITRK5 | c.2521C>T p.R841W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.76); catalogued as COSV100281209; called by muse, mutect2, varscan2
- SMARCC2 | c.2920C>T p.P974S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs200833916, COSV53240655, COSV99519651; called by muse, mutect2, varscan2
- SMOC1 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs764482616, COSV62759427; called by muse, mutect2, varscan2
- SMTN | c.2144C>T p.S715F | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100294929; called by muse, mutect2, varscan2
- SNAP25 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.67); catalogued as COSV99655116; called by muse, mutect2, varscan2
- SNAP91 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV52116649; called by muse, mutect2, varscan2
- SNCAIP | c.1675T>C p.S559P | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV99750400; called by muse, mutect2, varscan2
- SNTN | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.976); catalogued as COSV100662666; called by muse, mutect2, varscan2
- SORCS3 | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100865660; called by muse, mutect2, varscan2
- SORL1 | c.2710C>T p.R904W | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148966249; called by muse, mutect2, varscan2
- SP140L | c.221T>A p.F74Y | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99707699; called by muse, mutect2, varscan2
- SPAG17 | c.4942G>A p.D1648N | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.435); catalogued as rs759404757, COSV100310618; called by muse, mutect2, varscan2
- SPANXD | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 134/187 reads (72%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as rs782166949, COSV65152230; called by muse, mutect2, varscan2
- SPATC1 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101085324; called by muse, mutect2, varscan2
- SPHK2 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV99709627; called by muse, mutect2, varscan2
- SPRR4 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.083); catalogued as rs763331779, COSV100044708; called by muse, mutect2, varscan2
- SPTA1 | c.5365G>A p.E1789K | Missense Mutation (SNP) | VAF 84/157 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as COSV100935581; called by muse, mutect2, varscan2
- SPTAN1 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100823858, COSV100824023, COSV63985562; called by muse, mutect2, varscan2
- SRRM1 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as COSV100105326, COSV60482103; called by muse, mutect2, varscan2
- SRRM1 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.177); catalogued as COSV100105172; called by muse, mutect2, varscan2
- ST6GAL2 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 37/143 reads (26%) | PolyPhen probably damaging (0.932); catalogued as rs138821621; called by muse, mutect2, varscan2
- STAB1 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100402251; called by muse, mutect2, varscan2
- STAG1 | c.1265C>T p.S422L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV99366958; called by muse, mutect2, varscan2
- STXBP5L | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs775308756, COSV56507039; called by muse, mutect2, varscan2
- SUGP2 | c.2047C>T p.L683F | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100432346; called by muse, mutect2, varscan2
- SULF1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52695667, COSV52696143; called by muse, mutect2, varscan2
- SULT2A1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as rs370526585; called by muse, mutect2, varscan2
- SV2B | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs761763850, COSV57699424; called by muse, mutect2, varscan2
- SVEP1 | c.7706G>A p.G2569D | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99929004; called by muse, mutect2, varscan2
- SYNJ1 | c.4196C>T p.S1399F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.674); catalogued as COSV100449644; called by muse, mutect2, varscan2
- SYNPO2 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100206403; called by muse, mutect2, varscan2
- SYS1 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99713878, COSV99713991; called by muse, mutect2, varscan2
- SZT2 | c.4721G>A p.R1574Q (on ENST00000634258 / NM_001365999.1; = p.R1517Q on NM_015284.4) | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.268); catalogued as rs532357677, COSV100987676; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TACC2 | c.4454C>T p.S1485F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.311); catalogued as rs771707264, COSV57772152; called by muse, mutect2
- TAF1L | c.296G>A p.W99* | Nonsense Mutation (SNP) | VAF 57/183 reads (31%) | catalogued as COSV99645420; called by muse, mutect2, varscan2
- TBC1D2 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100580205; called by muse, mutect2, varscan2
- TBC1D2B | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs778871441, COSV100317768; called by muse, mutect2, varscan2
- TBC1D9 | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101464408; called by muse, mutect2, varscan2
- TBK1 | c.1418G>A p.R473K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.024); catalogued as COSV100538418; called by muse, mutect2, varscan2
- TBX15 | c.679G>A p.D227N (on ENST00000369429 / NM_001330677.2; = p.D121N on NM_152380.3) | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99254772, COSV99254967; called by muse, mutect2, varscan2
- TBX21 | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99456329; called by muse, mutect2, varscan2
- TCERG1L | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV100894587; called by muse, mutect2, varscan2
- TCL1A | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as COSV68085084; called by muse, mutect2, varscan2
- TESPA1 | c.812C>T p.S271F (on ENST00000316577 / NM_001098815.3; = p.S133F on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV100345651; called by muse, mutect2, varscan2
- TET1 | c.3446A>G p.K1149R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV101018898; called by muse, mutect2, varscan2
- TET1 | c.4742G>A p.W1581* | Nonsense Mutation (SNP) | VAF 49/117 reads (42%) | catalogued as COSV101018900; called by muse, mutect2, varscan2
- TEX13B | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 55/77 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100258499; called by muse, mutect2, varscan2
- TEX15 | c.6763C>G p.L2255V (on ENST00000256246; = p.L2638V on NM_001350162.2) | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as rs766906372, COSV99822134; called by muse, mutect2, varscan2
- TEX15 | c.116C>T p.S39L (on ENST00000256246; = p.S422L on NM_001350162.2) | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as rs1563245137, COSV99822137; called by muse, mutect2, varscan2
- TFDP2 | c.1016C>T p.S339F (on ENST00000489671 / NM_001178139.2; = p.S279F on NM_006286.5) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV100051206; called by muse, mutect2, varscan2
- TGM2 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as rs1012690368, COSV63931747; called by muse, mutect2, varscan2
- TGM6 | c.1966G>A p.D656N | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1408958125, COSV99172889; called by muse, mutect2, varscan2
- THEMIS | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.035); catalogued as rs770643870, COSV100965584; called by muse, mutect2, varscan2
- THSD7B | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.025); catalogued as rs866588841, COSV55651332; called by muse, mutect2, varscan2
- TIAM2 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as rs767995840, COSV59688424; called by muse, mutect2, varscan2
- TJP3 | c.1159C>T p.L387F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99516487; called by muse, mutect2, varscan2
- TLL1 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99289123; called by muse, mutect2, varscan2
- TLR4 | c.193C>T p.P65S (on ENST00000355622 / NM_138554.5; = p.P25S on NM_003266.4) | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.204); catalogued as rs772783306, COSV100790617, COSV62922626; called by muse, mutect2, varscan2
- TMC3 | c.2870C>T p.S957F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as COSV100846031; called by muse, mutect2
- TMC5 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as rs868458948, COSV66864859; called by muse, mutect2, varscan2
- TMEM132B | c.2557C>T p.P853S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as COSV100170921; called by muse, mutect2, varscan2
- TMEM200A | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.041); catalogued as COSV99760102; called by muse, mutect2, varscan2
- TMEM63C | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.573); catalogued as rs1224982578, COSV100029033; called by muse, mutect2, varscan2
- TMPRSS15 | c.2318G>A p.G773E | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99517340; called by muse, mutect2, varscan2
- TNC | c.3379C>T p.R1127W | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs775276668, COSV60780537; called by muse, mutect2, varscan2
- TNFSF15 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100928345; called by muse, mutect2, varscan2
- TNIK | c.1853G>A p.G618D | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.05); catalogued as COSV99459590; called by muse, mutect2, varscan2
- TNN | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated (0.24); PolyPhen benign (0.331); catalogued as COSV99511508, COSV99513040; called by muse, mutect2, varscan2
- TNR | c.3766C>T p.R1256C | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144730675, COSV54920473, COSV99691507; called by muse, mutect2, varscan2
- TNR | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99691583; called by muse, mutect2, varscan2
- TP53AIP1 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV101513114; called by muse, mutect2, varscan2
- TP63 | c.356G>A p.S119N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV99288918; called by muse, mutect2, varscan2
- TRANK1 | c.5381G>A p.G1794E | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.311); catalogued as COSV57157803; called by muse, mutect2, varscan2
- TRANK1 | c.2387C>T p.S796L | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV100084803; called by muse, mutect2, varscan2
- TRAV13-2 | c.89C>T p.T30I | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as rs1382126765; called by muse, mutect2, varscan2
- TREM1 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99776159, COSV99776318; called by muse, mutect2, varscan2
- TRHR | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs145633647; called by muse, mutect2, varscan2
- TRIM58 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs886680114, COSV63569392; called by muse, mutect2
- TRIP12 | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.676); catalogued as COSV99390945; called by muse, mutect2, varscan2
- TRPV5 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 51/70 reads (73%) | SIFT tolerated (0.55); PolyPhen benign (0.033); catalogued as rs1315120023, COSV99521048; called by muse, mutect2, varscan2
- TSGA10 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as rs774847320, COSV61822824; called by muse, mutect2, varscan2
- TSPAN16 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs750213552, COSV57441837; called by muse, mutect2, varscan2
- TSPAN16 | c.170T>A p.V57D | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV100368499; called by muse, mutect2, varscan2
- TSPAN33 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99179812; called by muse, mutect2, varscan2
- TTC24 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100964367; called by muse, varscan2
- TTC39A | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 77/215 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV99397110; called by muse, mutect2, varscan2
- TTLL6 | c.1401G>A p.R467= (on ENST00000393382 / NM_001130918.3; = p.R160= on NM_173623.3) | Splice Region (SNP) | VAF 30/103 reads (29%) | catalogued as COSV100938227; called by muse, mutect2, varscan2
- TTN | c.65513G>A p.R21838Q (on ENST00000591111; = p.R14414Q on NM_003319.4) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | PolyPhen possibly damaging (0.786); catalogued as rs140127488, COSV60128822, COSV60158704; called by muse, mutect2, varscan2
- TTN | c.5794A>T p.R1932W (on ENST00000591111; = p.R1886W on NM_003319.4) | Missense Mutation (SNP) | VAF 53/138 reads (38%) | PolyPhen possibly damaging (0.898); catalogued as COSV100630259; called by muse, mutect2, varscan2
- TUT7 | c.3267A>T p.K1089N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV99463667; called by muse, mutect2, varscan2
- UBR1 | c.3946C>T p.R1316* | Nonsense Mutation (SNP) | VAF 31/110 reads (28%) | catalogued as rs373699629, COSV99317877; called by muse, mutect2, varscan2
- UBXN4 | c.1267C>T p.L423F | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs1031936413, COSV99739637; called by muse, mutect2, varscan2
- UCN3 | c.358T>C p.F120L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV100991743; called by muse, mutect2, varscan2
- UGT2B28 | c.1499G>C p.C500S | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100159068; called by muse, mutect2, varscan2
- UGT2B4 | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100522667; called by muse, mutect2, varscan2
- UNC79 | c.765G>A p.W255* (on ENST00000393151 / NM_001346218.2; = p.W78* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV99829864; called by muse, mutect2, varscan2
- UQCRB | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1382173944, COSV99749293; called by muse, mutect2, varscan2
- UQCRFS1 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100508178; called by muse, mutect2, varscan2
- URB2 | c.3377C>T p.A1126V | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV99271916; called by muse, mutect2, varscan2
- USH2A | c.13823G>A p.R4608Q | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.04); catalogued as rs776471973, COSV56333866, COSV56354805; called by muse, mutect2, varscan2
- USH2A | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV56362758, COSV56462745; called by muse, mutect2, varscan2
- USP10 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV99551726; called by muse, mutect2, varscan2
- USP31 | c.3161C>T p.S1054L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV99565904; called by muse, mutect2, varscan2
- VCAM1 | c.455T>C p.L152S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99658934; called by muse, mutect2
- VDAC1 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1405966854, COSV99527339; called by muse, mutect2, varscan2
- VEPH1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100747906; called by muse, mutect2, varscan2
- VPS13B | c.8144T>C p.V2715A | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV100663690; called by muse, mutect2, varscan2
- VSTM4 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.937); catalogued as rs761670836, COSV100039542; called by muse, mutect2, varscan2
- VWA3A | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV67014045; called by muse, mutect2
- WDR26 | c.1784G>A p.S595N (on ENST00000414423 / NM_001379403.1; = p.S495N on NM_025160.7) | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.065); catalogued as COSV99691545; called by muse, mutect2
- WDR49 | c.268G>A p.D90N (on ENST00000308378 / NM_001366158.1; = p.D431N on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57708795; called by muse, mutect2, varscan2
- WDR93 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99175835; called by muse, mutect2, varscan2
- WIPF1 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV55814012; called by muse, mutect2, varscan2
- WIPF1 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.09); catalogued as rs759804410, COSV55821211; called by muse, mutect2, varscan2
- WNT9A | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV55294717; called by muse, mutect2, varscan2
- WWP1 | c.2636G>A p.G879D | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs774414394, COSV99617231; called by muse, mutect2, varscan2
- WWP2 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 133/389 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100598787; called by muse, mutect2, varscan2
- XIRP2 | c.4082A>G p.E1361G (on ENST00000628543; = p.E1536G on NM_152381.6) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.638); catalogued as COSV99747473; called by muse, mutect2, varscan2
- XPO4 | c.1136C>A p.T379N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99689177; called by muse, varscan2
- XPO6 | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV100485369; called by muse, mutect2, varscan2
- YTHDF3 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); catalogued as COSV101572423; called by muse, mutect2, varscan2
- ZC3HC1 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 55/90 reads (61%) | catalogued as rs372808552, COSV100316062; called by muse, mutect2, varscan2
- ZFY | c.1478T>A p.F493Y | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT tolerated (0.5); PolyPhen benign (0.148); catalogued as COSV99324296; called by muse, mutect2, varscan2
- ZMAT1 | c.659A>T p.Y220F | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT tolerated (0.83); PolyPhen benign (0.059); catalogued as COSV100858939; called by muse, mutect2, varscan2
- ZMIZ2 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV99537211; called by muse, mutect2, varscan2
- ZNF12 | c.1895C>T p.P632L (on ENST00000405858 / NM_016265.4; = p.P594L on NM_006956.3) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1293392737, COSV100703894; called by muse, mutect2, varscan2
- ZNF236 | c.4807C>T p.P1603S | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as rs1399722595, COSV53499832, COSV99471252; called by muse, mutect2, varscan2
- ZNF462 | c.5817T>A p.D1939E | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.057); catalogued as COSV99473340; called by muse, mutect2, varscan2
- ZNF479 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs535878108, COSV58635779; called by muse, mutect2, varscan2
- ZNF536 | c.1559G>A p.S520N | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV100835904; called by muse, mutect2, varscan2
- ZNF57 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as rs199768041, COSV60982569; called by muse, mutect2, varscan2
- ZNF676 | c.803G>A p.R268Q (on ENST00000650058; = p.R236Q on NM_001001411.3) | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.706); catalogued as rs759564847, COSV68092109; called by muse, mutect2, varscan2
- ZNF76 | c.552G>A p.V184= | Splice Region (SNP) | VAF 51/180 reads (28%) | catalogued as rs749765488, COSV99987964; called by muse, mutect2, varscan2
- ZNF761 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.708); catalogued as COSV100483483; called by muse, mutect2, varscan2
- ZNF804B | c.1725G>A p.M575I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs764812300, COSV60815799, COSV60822843, COSV60866027; called by muse, mutect2, varscan2
- ZNF831 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100926263; called by muse, mutect2, varscan2
- ZP1 | c.318+1G>A p.X106_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99612834; called by mutect2, varscan2
- CFAP74 | c.4236G>A p.G1412= | Splice Region (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2
- CFAP74 | c.4235G>A p.G1412E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2
- GAS2L2 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GDF10 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- GPAT4 | c.305_341del p.K102Tfs*18 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | called by mutect2, pindel
- HAVCR1 | c.674-1G>A p.X225_splice | Splice Site (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2
- HYDIN | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- IGHV3-48 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 49/147 reads (33%) | called by muse, mutect2, varscan2
- IGHV3-74 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 95/243 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- IGKV1D-17 | c.119G>A p.R40K | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NBPF7 | n.606G>A | Splice Region (SNP) | VAF 33/140 reads (24%) | called by muse, mutect2, varscan2
- PRAMEF19 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RASSF10 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TRAV8-6 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- UBE2O | c.519_520del p.A174Rfs*33 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | called by pindel, varscan2
- WDR35 | c.3396-1G>A p.X1132_splice (on ENST00000345530 / NM_001006657.2; = p.X1121_splice on NM_020779.4) | Splice Site (SNP) | VAF 29/92 reads (32%) | called by muse, mutect2
- XKR3 | c.1208G>A p.W403* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- ZFX | c.700_707delinsT p.T234Wfs*30 | Frame Shift Del (DEL) | VAF 50/75 reads (67%) | called by pindel, varscan2*
- ABCA4 | c.5499C>T p.L1833= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as rs772616044, COSV100933245; called by muse, mutect2, varscan2
- ABCA8 | c.708C>T p.F236= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99286931; called by muse, mutect2, varscan2
- ABCC1 | c.4104C>T p.F1368= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs376860266; called by muse, mutect2, varscan2
- ABCC8 | c.651C>T p.F217= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as rs1378258469, COSV100217729; called by muse, mutect2, varscan2
- ACAP1 | c.1284G>A p.P428= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as rs373535482; called by muse, mutect2, varscan2
- ACE | c.3180C>T p.I1060= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs754344947, COSV52003209; called by muse, mutect2, varscan2
- ACSM2B | c.708G>A p.S236= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as rs747849079, COSV100313149; called by muse, mutect2, varscan2
- ADAM11 | c.1866C>T p.V622= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV99567837; called by muse, mutect2, varscan2
- ADAM23 | c.2394C>T p.I798= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs765657820, COSV100008841; called by muse, varscan2
- ADAMTS13 | c.876C>T p.S292= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs1554786737, COSV100747218; called by muse, mutect2
- ADAMTS8 | c.1833C>T p.V611= | Silent (SNP) | VAF 50/135 reads (37%) | catalogued as COSV99961485; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4614C>T p.I1538= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs369423383; called by muse, mutect2, varscan2
- ADH1A | c.516C>T p.L172= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV99265982; called by muse, mutect2, varscan2
- AFP | c.54C>T p.S18= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV99890412; called by muse, mutect2, varscan2
- AHNAK2 | c.13503C>T p.S4501= | Silent (SNP) | VAF 56/200 reads (28%) | catalogued as COSV100318962; called by muse, mutect2, varscan2
- AL121899.2 | c.762G>A p.G254= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV67350723; called by muse, mutect2, varscan2
- ALG2 | c.930C>T p.S310= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV99445731; called by muse, mutect2, varscan2
- ALK | c.3942C>T p.S1314= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV66580519; called by muse, mutect2, varscan2
347 further variants in this file (0 protein-altering or splice-affecting, 320 silent, 27 other) are not listed here.
